Somatic mutation profile of tumor specimen 0DVKG8 from CCDI case PBCMZY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 15.6 years (5,681 days).
Specimen 0DVKG8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afd95709-4f54-4189-ae3f-b8b28529e2c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKGA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10f324a4-2a71-42cb-b3ed-0435ee339ba4

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF426 | c.712T>C p.Y238H | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.515); catalogued as rs916754251, COSV99465449; called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 26/849 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HAVCR1 | c.944T>A p.I315N | Missense Mutation (SNP) | VAF 36/777 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 19/611 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- RANBP2 | c.9580G>A p.D3194N | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2
- RAPGEF2 | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ALDH5A1 | c.870+87C>A | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ATP5F1A | c.60+48G>C | Intron (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1959C>G | Intron (SNP) | VAF 50/743 reads (7%) | catalogued as COSV51772967; called by muse, mutect2
